Somatic mutation profile of tumor specimen 0DUHHY from CCDI case PBCLFW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.3 years (2,678 days).
Specimen 0DUHHY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18bbcfc8-f06a-41e1-9959-67e9596e6fd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHGB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63224674-1251-4bad-a1ad-5e84bac79623

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Intron 4, 5'UTR 2, Splice Region 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 151/360 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs763782134, COSV100419865; called by muse, mutect2, varscan2
- AKAP4 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 138/213 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs1557203972; called by muse, mutect2, varscan2
- BACH1 | c.2033C>A p.A678E | Missense Mutation (SNP) | VAF 37/891 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs1273962397; called by muse, mutect2
- CDC42BPG | c.2626-8C>G | Splice Region (SNP) | VAF 9/196 reads (5%) | catalogued as rs1250692294; called by muse, mutect2
- CHI3L1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs776581548, COSV55139238; called by muse, mutect2, varscan2
- CSMD3 | c.2249C>T p.T750M (on ENST00000297405 / NM_001363185.1; = p.T646M on NM_052900.3) | Missense Mutation (SNP) | VAF 118/526 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1490537303, COSV52337134, COSV99820895; called by mutect2, varscan2
- GABRB2 | c.1440C>G p.D480E (on ENST00000274547; = p.D442E on NM_000813.3) | Missense Mutation (SNP) | VAF 26/634 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV50950900; called by muse, mutect2
- HRNR | c.7181G>C p.G2394A | Missense Mutation (SNP) | VAF 34/1124 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as rs1232700591; called by muse, mutect2
- SH2B3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 91/602 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as rs1263604332; called by muse, mutect2, varscan2
- TNN | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1385614673; called by muse, mutect2, varscan2
- ZBTB12 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 130/350 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201031797; called by muse, mutect2, varscan2
- ABCB5 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 172/846 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by mutect2, varscan2
- ADRA1A | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 135/459 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ANKFN1 | c.1709T>G p.L570R | Missense Mutation (SNP) | VAF 138/1060 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ART5 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC40 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 321/1123 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYM | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 70/691 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EFCAB11 | c.302C>G p.T101R | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NIT2 | c.497C>G p.A166G | Missense Mutation (SNP) | VAF 156/537 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OPRPN | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- OR2T1 | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PIK3AP1 | c.1811G>A p.G604D | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM34 | c.1199G>C p.S400T | Missense Mutation (SNP) | VAF 160/575 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- RIN3 | c.2435A>G p.E812G | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPNS2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TM2D3 | c.670_672dup p.I224dup (on ENST00000333202 / NM_078474.3; = p.I198dup on NM_025141.3) | In Frame Ins (INS) | VAF 177/448 reads (40%) | called by mutect2, pindel, varscan2
- UROC1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VPS13B | c.9124G>A p.V3042I | Missense Mutation (SNP) | VAF 121/408 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP4F8 | c.999G>A p.T333= | Silent (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- KIAA0825 | c.3435T>C p.Y1145= | Silent (SNP) | VAF 104/192 reads (54%) | catalogued as rs1249045305; called by muse, mutect2, varscan2
- PCED1B | c.537C>A p.P179= | Silent (SNP) | VAF 130/396 reads (33%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9546C>T p.V3182= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as rs754890232; called by muse, mutect2, varscan2
- TINF2 | c.1188T>C p.S396= | Silent (SNP) | VAF 35/282 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS11E | c.1008C>A p.L336= | Silent (SNP) | VAF 125/558 reads (22%) | catalogued as COSV100542348; called by muse, mutect2, varscan2
- CRCP | c.-53G>A | 5'UTR (SNP) | VAF 36/980 reads (4%) | called by muse, mutect2
- LSG1 | c.1174-99del | Intron (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- RPS16 | c.248-32C>T | Intron (SNP) | VAF 74/260 reads (28%) | catalogued as rs1458174219; called by muse, mutect2, varscan2
- SLC6A3 | c.-30G>A | 5'UTR (SNP) | VAF 40/78 reads (51%) | catalogued as rs369951316; called by muse, mutect2, varscan2
- STK11IP | c.342+41T>C | Intron (SNP) | VAF 11/404 reads (3%) | called by muse, mutect2
- TMEM104 | c.*2402C>T | 3'UTR (SNP) | VAF 36/628 reads (6%) | called by muse, mutect2
- WDR59 | c.1100-47dup | Intron (INS) | VAF 50/148 reads (34%) | called by mutect2, pindel, varscan2
